Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-5329, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-5329-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Soft-Tissue: left lateral tongue margin Quick section
2. Soft-Tissue: left anterior tongue margin
3. Soft-Tissue: left posterior tongue margin
4. Soft-Tissue: deep margin
5. Soft-Tissue: left alveolar margin
6. Soft Tissue: Contents of left neck
7. Oral Cavity: Left sublingual gland
8. Oral Cavity: Contents left tongue & floor of mouth short suture anterior long suture posterior nylon double long suture inferior
9. Soft Tissue: Revised: Deep margin single chip anterior double chip posterior triple chip inferior

Diagnosis

1. Left lateral margin.
Negative for malignancy.
2. Left anterior margin.
Negative for malignancy.
3. Left posterior margin.
Negative for malignancy.
4. Deep margin.
Negative for malignancy.
5. Left alveolar margin.
Negative for malignancy.
6. Left neck contents:
Twenty nine lymph nodes negative for tumour (0/29).
Submandibular gland with no pathologic changes.
7. Left sublingual gland.
Salivary gland tissue with mild chronic sialadenitis.
Negative for malignancy.
8. Oral cavity' left tongue and floor of mouth.
Squamous cell carcinoma, poorly differentiated.
- a. Maximal tumour dimension 2.8 cm.
- b. Tumour thickness 0.9 cm.

[page 2 of 3]
- c. No perineural invasion.
- d. No vascular/lymphatic invasion.
- e. Moderate to severe squamous dysplasia is present.
- f. All margins negative for tumour.

9. Revised deep margin.
Negative for malignancy.

Synoptic Data

Specimen Type:	Resection: Partial glossectomy
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 2.8 cm Tumor thickness: 0.9 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Absent
Additional Pathologic Findings:	None identified
Margins:	Margins uninvolved by tumor Margins uninvolved by tumor - Distance of tumor from closest margin: 0.4 cm Margins: deep
Pathologic Staging (pTNM):	pT2: Tumor of lip or oral cavity more than 2 cm but not more than 4 cm in greatest dimension pN0: No regional lymph node metastasis for aerodigestive sites Number of regional lymph nodes examined: 29 Number of regional lymph nodes involved: 0 pMX: Distant metastasis cannot be assessed

Gross Description

1. The specimen is labeled with the patient's name and as "Soft-Tissue: Left lateral tongue margin quick section". It consists of a fragment of tissue measuring 1.5 x 0.7 x 0.5 cm. The specimen is bisected and submitted in toto for frozen section.
1A frozen section control
2. The specimen is labeled with the patient's name and as "Soft-Tissue: Left anterior tongue margin". It consists of a fragment of tissue measuring 0.7 x 0.6 x 0.2 cm. The specimen is submitted in toto for frozen section.
2A frozen section control
3. The specimen is labeled with the patient's name and as "Soft-Tissue: Left posterior tongue margin". It consists of a fragment of tissue measuring 1.4 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.
3A frozen section control
4. The specimen is labeled with the patient's name and as "Soft-Tissue: Deep margin". It consists of a fragment of tissue measuring 0.8 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.
4A frozen section control
5. The specimen is labeled with the patient's name and as "Soft-Tissue: Left alveolar margin". It consists of a fragment of tissue measuring 1.7 x 0.5 x 0.3 cm. The specimen is submitted in toto for frozen section.

[page 3 of 3]
5A frozen section control

6. The specimen is labeled with the patient's name and as "Soft Tissue: Contents of left neck". It consists of an oriented left neck dissection with dimensions of 10.7 x 11.0 x 1.5 cm. Two portions of unremarkable muscle are identified and measure 2.4 x 1.5 x 0.3 cm and 2.8 x 1.5 x 0.6 cm. The submandibular gland measures 3.8 x 2.9 x 1.4 cm and is unremarkable. Multiple lymph nodes ranging from 0.1 to 2.5 cm are identified in multiple levels. Representative sections are submitted as follows:

- 6A one lymph node, level IA
- 6B one lymph node, level IA
- 6C one lymph node, level IA
- 6D submandibular gland
- 6E-6G one lymph node per block, level IB
- 6H two lymph nodes, level IIB
- 6I one lymph node, level IIB
- 6J one lymph node, level IIA
- 6K one lymph node, level IIA
- 6L one lymph node, level IIA
- 6M multiple lymph nodes, level III
- 6N two lymph nodes, level III
- 6O-6P one lymph node per block, level III
- 6Q-6R multiple lymph nodes per block, level IV
- 6S one lymph node, level IV
- 6T one lymph node, level IV

7. The specimen is labeled with the patient's name and as "Oral Cavity: Left sublingual gland". It consists of one piece of tissue measuring 1.4 x 1.2 x 0.5 cm.

7A specimen in toto

8. The specimen is labeled the patient's name and as "Oral Cavity: Contents left tongue & floor of mouth short suture anterior, long suture posterior, nylon double long suture inferior". It consists of an oriented portion of left lateral tongue, measuring 3.0 cm SI x 1.9 cm ML x 4.7 cm AP. There is a well-circumscribed tumor involving the left lateral surface of the tongue. The tumor measures 2.1 cm SI x 1.2 cm ML x 2.8 cm AP. The tumor is solid and firm and is located at the lateral margin, 0.2 cm from the medial/deep margin, 0.6 cm from the superior margin, 0.4 cm from the inferior margin, 0.6 cm from the anterior margin, and 0.5 cm from the supero-posterior margin. Cross sections reveal a portion of left sublingual gland, measuring 1.4 cm SI x 0.6 cm ML x 2.0 cm AP. All the margins of the specimen are painted with Silver nitrate. The superior aspect is also painted green. Two pieces of tumor and one piece of normal tongue are taken for the tissue bank. Representative sections are submitted.

- 8A anterior margin and tumor
- 8B-8C one full thickness section of tumor
- 8D-8E one full thickness section of tumor
- 8F-8G tumor
- 8H supero-posterior margin and tumor

9. The specimen is labeled the patient's name and as "Soft Tissue: Revised: Deep margin single clip anterior, double clip posterior, triple clip inferior". It consists of an unremarkable portion of tongue measuring 2.5 cm SI x 0.9 cm ML x 4.0 cm AP. The margins of the specimen have been painted with Silver nitrate. The specimen is submitted in toto.

- 9A anterior margin, en face
- 9B-9G remaining specimen, anterior to posterior
- 9H posterior margin, en face

Source: NCI Genomic Data Commons file 4b8c8df2-7c62-495b-ba0a-26625485b05c (TCGA-CQ-5329.A676CB35-350F-43F3-BBFA-B9B200A658FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).